Surgical pathology report (de-identified scan), TCGA case TCGA-60-2719, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2719-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R LYMPH NODE
B. LEVEL 7
C. 4L LYMPH NODE
D. RIGHT LEVEL 4 LNODE
E. RIGHT UPPER LOBE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

RUL small cell lung ca

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-FSD: Lymph nodes - negative for tumor

FSE: Bronchial margin - negative for tumor

GROSS DESCRIPTION:**A. 4R LYMPH NODE**

Received fresh for frozen section is a tan-pink lymph node 0.4 x 0.2 x 0.1 cm. The specimen is submitted entirely for frozen section in FSA1.

B. LEVEL 7

Is a tan-pink aggregate of lymphoid tissue 0.7 x 0.4 x 0.2 cm. The entire specimen is submitted for frozen section in FSB1.

C. 4L LYMPH NODE

Is an aggregate of lymphoid tissue 0.5 x 0.3 x 0.2 cm. The specimen is submitted entirely for frozen section in FSC1.

[page 2 of 3]
[REDACTED]

D. RIGHT LEVEL 4 LYMPH NODE

Is a tan-pink aggregate of lymphoid tissue 0.8 x 0.8 x 0.3 cm. The specimen is submitted entirely for frozen section in FSD1.

[REDACTED]

E. LUNG, RIGHT UPPER LOBE, LOBECTOMY:

Received fresh and labeled with the patient name [REDACTED] "right upper lobe", is a 121-gram lobectomy specimen measuring 14.5 x 10.7 x 2.3 cm. There is a defect on the pleural surface exposing a mass measuring 3.0 x 2.5 x 1.5 cm. The mass is hemorrhagic and necrotic. It extends to within 0.3 cm of the pleural margin and 1.2 cm from the bronchial margin. A shave section is taken of the bronchial margin for frozen section. The bronchi are opened and they have a smooth tan appearance. The lung is sectioned and the parenchyma has a variegated pink and anthracotic appearance as well as areas of congestion. Possible anthracotic lymph nodes are identified. Portions of mass were submitted for tissue procurement. Representative sections are submitted as follows:

FSE1: Shave section of bronchial margin

E2-E5: Sections of mass including relationship to normal appearing parenchyma and pleural margin

E6: Additional portions of uninvolved parenchyma

E7: Possible lymph nodes

[REDACTED]

DIAGNOSIS:

A. 4R RIGHT LYMPH NODE

- ANTHRACOSIS OF ONE LYMPH NODE - NEGATIVE FOR TUMOR (0/1)

B. LEVEL 7 LYMPH NODE:

- ONE LYMPH NODE - NEGATIVE FOR TUMOR (0/1)

C. 4L LEFT LYMPH NODE:

- ONE LYMPH NODE - NEGATIVE FOR TUMOR (0/1)

D. RIGHT LEVEL 4 LYMPH NODE:

- ONE LYMPH NODE - NEGATIVE FOR TUMOR (0/1)

E. LUNG, RIGHT UPPER LOBE, LOBECTOMY SPECIMEN:

- NON SMALL CELL CARCINOMA (CONSISTENT WITH MODERATE TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA) WITH AREAS OF NECROSIS OF UPPER LOBE OF RIGHT LUNG
- SIZE OF TUMOR 3.0 X 2.5 X 1.5 CM
- CONGESTION AND FOCAL ATELECTATIC CHANGE
- SIX PERIBRONCHIAL LYMPH NODES - (0/6) NEGATIVE FOR TUMOR
- [REDACTED]

[page 3 of 3]
[REDACTED]

- MARGINS OF RESECTION - NEGATIVE FOR TUMOR

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: E: RIGHT UPPER LOBE

Surgical Procedure: Lobectomy

Laterality: Right

Tumor Site: Upper lobe

Tumor Location: Central

Tumor Size: Greatest diameter: 3cm

Additional dimensions: 2.5cm x 1.5cm

WHO CLASSIFICATION

Squamous cell carcinoma

Comment(s): *Non small cell carcinoma*

Histologic Grade: poorly to moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Tumor Distance from margin: 1.2cm

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)

Negative 0 / 6

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)

Negative 0 / 3

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular

Negative 0 / 1

Non-Neoplastic Lung: Emphysematous changes

congestion and focal atelectatic change

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 1 N 0 M x

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 82f8f775-635b-4495-9960-f13c239f41f9 (TCGA-60-2719.1843B1C7-9197-4595-AD5D-862E0F1EC3F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).